Gene-level copy-number profile of tumor specimen TCGA-CD-8534-01A from TCGA case TCGA-CD-8534, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 41.7 years (15,227 days).
Specimen TCGA-CD-8534-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.1b076b56-707f-4fa8-ac2e-d88b7c3f291a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-8534-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/029d17f3-08a0-45b7-b873-b487dbfbedf2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 142; copy number 1: 18,472; copy number 2: 38,414; copy number 3: 2,508; copy number 6: 43; copy number 9: 150; copy number 11: 86.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-8534-01A-11D-2338-01): tumor purity 0.95, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 142 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,032,884–186,422,432, 5 genes (within-gene range 0–1): LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3.
- chr4:49,096–337,433, 12 genes: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4.
- chr4:338,097–342,962, 2 genes: AC079140.1, AC079140.2.
- chr9:21,135,598–29,826,711, 113 genes (broad region; genes not listed).
- chr11:134,655,769–135,075,908, 10 genes: AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 279 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:89,882,353–101,018,949, 279 genes, copy number 6–11 (within-gene range 1–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,051. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
